CCDI case PBCEHM — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/9c53d77d-7c92-485b-8aaf-04b51ad6dadd

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Neoplasm, malignant: ICD-O-3 morphology code: 8000/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 2.7 years (1,000 days).

Biospecimens (3 samples)
- Sample 0DPYD7: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DPYDX: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DPYE4: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
